Gene-level copy-number profile of tumor specimen ALCH-B3A0-TTP1-A from ALCHEMIST case ALCH-B3A0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.1 years (21,935 days).
Specimen ALCH-B3A0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2c17a5ed-9fb2-43da-8b14-0b9849e2445f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3A0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/8ad21be6-88d3-49cb-bf54-d86e75372cbb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 300; copy number 1: 14,945; copy number 2: 33,538; copy number 3: 8,426; copy number 4: 1,160; copy number 5: 15; copy number 6: 1; copy number 7: 13; copy number 8: 2; copy number 27: 2.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:84,315,108–84,350,774, 1 gene (within-gene range 0–2): AC106874.1.
- chr2:132,253,154–132,257,080, 2 genes (within-gene range 0–2): RNA5-8SP5, MIR663B.
- chr3:75,370,448–75,538,029, 9 genes: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr4:63,350,114–63,351,472, 1 gene: LARP1BP1.
- chr6:149,879,962–149,881,572, 1 gene (within-gene range 0–1): CCT7P1.
- chr6:157,934,168–157,934,257, 1 gene (within-gene range 0–1): RNU6-786P.
- chr8:31,497,423–31,498,612, 1 gene: AC068672.1.
- chr10:95,141,925–95,173,187, 2 genes: AL157834.4, AL157834.3.
- chr12:38,078,529–38,087,392, 2 genes: AK6P2, CLUHP8.
- chr12:101,066,734–101,069,232, 1 gene (within-gene range 0–2): SNX5P2.
- chr15:37,921,939–37,967,724, 1 gene: TMCO5A.
- chr16:32,649,193–32,788,944, 13 genes: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:74,305,127–74,441,937, 9 genes (within-gene range 0–1): AC009120.2, AC009120.1, AC009120.3, AC009053.1, AC009053.2, NPIPB15, AC009053.4, CLEC18B, AC009053.3.
- chr17:16,414,524–16,492,193, 9 genes: AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr19:5,865,826–5,904,006, 4 genes: FUT5, AC024592.3, NDUFA11, AC024592.1.
- chr19:5,904,872–5,910,853, 1 gene (within-gene range 0–1): VMAC.
- chr19:19,512,418–19,628,930, 9 genes: TSSK6, NDUFA13, AC011448.1, YJEFN3, CILP2, PBX4, PHF5CP, AC002306.1, LPAR2.
- chr19:27,639,300–27,639,665, 1 gene (within-gene range 0–1): AC112702.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,131,634–235,328,219, 3 genes, copy number 5 (within-gene range 3–5): ARID4B, MIR4753, RPL23AP23.
- chr7:63,326,674–63,359,306, 7 genes, copy number 5: AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:144,176,740–144,356,181, 13 genes, copy number 7 (within-gene range 4–33): OR2AO1P, CTAGE4, ARHGEF35, ARHGEF35-AS1, OR2A42, OR2A20P, AC074386.1, OR2A7, CTAGE8, ARHGEF34P, OR2A9P, OR2A1-AS1, OR2A1.
- chr9:137,277,726–137,302,271, 5 genes, copy number 5: TOR4A, BX255925.2, BX255925.1, BX255925.4, NRARP.
- chr16:32,475,051–32,478,250, 1 gene, copy number 6: ABCD1P3.
- chr16:32,845,964–32,885,501, 4 genes, copy number 8–27 (within-gene range 2–27): AC142086.2, IGHV2OR16-5, BCAP31P2, SLC6A10P.

Autosomal genes at a single copy (total copy number 1): 12,836. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
